MMRF case MMRF_2325 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a901262a-f985-4054-8bdf-6557a8a80b98

Demographics
Sex at birth: male; Age at index: 44 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 45.0 years (16,421 days); ISS stage: I; Days to last known disease status: 821 days (2.2 years); Days to last follow up: 821 days (2.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -25 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.06 mg/dL; Immunoglobulin G 2.91 g/L; Immunoglobulin A 42.5 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 10.2 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0.139 mg/dL.
- Day 92 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 2.33 g/L; Immunoglobulin A 5.06 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 4.07 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 183: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.55 mg/dL; Immunoglobulin G 1.98 g/L; Immunoglobulin A 2.55 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 5.9 g/dL; Glucose 5.5 mmol/L.
- Day 260 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 1.81 g/L; Immunoglobulin A 1.46 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 4.03 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.4 g/dL; Glucose 6 mmol/L.
- Day 373 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 2.12 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 5.8 g/dL; Glucose 8.36 mmol/L.
- Day 457 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 352 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 5.8 g/dL; Glucose 4.95 mmol/L.
- Day 540 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 9.35 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.34 mmol/L.
- Day 624 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 737 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 821 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 2.88 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6.5 g/dL; Glucose 6.93 mmol/L.

Other clinical attributes
- Day -25: Weight: 84 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2325_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -25 days.
- Sample MMRF_2325_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -25 days.
